Gene-level copy-number profile of tumor specimen TCGA-EE-A20H-06A from TCGA case TCGA-EE-A20H, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 69.3 years (25,314 days).
Specimen TCGA-EE-A20H-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.3ff0630e-ef9c-4ef6-9e73-1d1238ffbba3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A20H-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/cf51e9bd-01f8-4abf-affe-98dd26de8fed

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 24; copy number 1: 1,085; copy number 2: 15,909; copy number 3: 14,488; copy number 4: 22,897; copy number 5: 2,740; copy number 6: 2,254; copy number 7: 243; copy number 8: 14; copy number 20: 14; copy number 22: 47; copy number 27: 57; copy number 28: 17; copy number 29: 30; copy number 32: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A20H-06A-11D-A191-01): tumor purity 0.95, ploidy 3.3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:89,825,964–90,019,549, 1 gene (within-gene range 0–2): AL161629.1.
- chr12:126,094,112–126,177,632, 1 gene (within-gene range 0–3): LINC02359.
- chr12:126,130,166–127,060,565, 22 genes (within-gene range 0–3): AC005858.3, AC005858.1, AC005888.1, AC007368.1, LINC02825, LINC02347, FAM32EP, AC006065.1, NDUFA5P6, AC006065.4, AC006065.2, AC006065.3, AC006065.5, AC006065.6, LINC02824, LINC00943, LINC00944, AC078878.1, LINC02372, AC078878.2, HSPE1P20, LINC02405.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 166 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:224,703,764–225,042,468, 3 genes, copy number 28: CCDC195, DOCK10, MIR4439.
- chr5:50,603,229–50,846,519, 4 genes, copy number 22 (within-gene range 2–22): AC112187.2, AC112187.1, AC112187.3, PARP8.
- chr5:165,905,126–165,905,608, 1 gene, copy number 32: AC008489.1.
- chr5:170,028,488–170,736,632, 14 genes, copy number 20 (within-gene range 4–20): MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, AC034199.2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1.
- chr12:41,188,320–42,717,120, 30 genes, copy number 29 (within-gene range 3–29): PDZRN4, AC090531.1, RNA5SP360, MTND2P17, MTND1P24, LINC02400, AC090630.1, AC006197.1, AC006197.2, AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3, LINC02402, AC079600.2, AC079600.1, LINC02451, RPS27P21, LINC02450.
- chr12:43,560,784–44,503,596, 14 genes, copy number 28: AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2.
- chr12:50,392,383–52,753,821, 100 genes, copy number 22–27 (within-gene range 3–27) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,085. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
